Gene-level copy-number profile of tumor specimen TCGA-24-0980-01A from TCGA case TCGA-24-0980, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.6 years (19,579 days).
Specimen TCGA-24-0980-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ea0d83ca-b20e-426b-aca5-9ba06a936d89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-0980-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/609cad70-4388-4cec-8225-b3bddccb4139

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,880; copy number 2: 41,232; copy number 3: 1,912; copy number 4: 734; copy number 5: 310; copy number 6: 685; copy number 7: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-0980-01A-01D-0399-01): tumor purity 0.73, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 526 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:7,041,899–10,295,579, 111 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:89,933,331–97,853,253, 134 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:110,766,863–121,994,185, 88 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr8:124,811,042–141,308,305, 193 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,475. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
